Surgical pathology report (de-identified scan), TCGA case TCGA-05-4396, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4396-01A (Primary Tumor).

Main diagnosis/diagnoses:

Very extensive, pneumonia-like, imposing bronchopulmonary mixed adenocarcinoma with a predominantly tubulopapillary and bronchioloalveolar pattern, as well as slight mucin formation and formation of numerous, in parts very small foci within the parenchyma and minimal pleural invasion and lymphogenous metastatic spread.

Comment/supplementary remark:

By definition, the foci of mixed adenocarcinoma detected not only in the immediate environment of the tumor, but in some cases only at microscopic level, are to be classified satellite nodes in the ipsilateral lobe, which - bearing in mind the location of the lymph node micrometastases (samples 5.), 7.) and very probably also 1.)), as well as the absence of tumor in the resection margins of the bronchus and the vessels - gives a tumor classification of pT4 pN1 R0. But in view of the presentation of the tumor and the partial bronchioloalveolar differentiation, the interpretation can be just as easily be supported or perhaps even favored that this is a primary multifocal tumor manifestation. This would correspond to pT2(m). The stage grouping IIIB thus competes with IIB. The main tumor mass lies in segments 6 and 9 of the resected right lower lobe. The largest of the metastases found in the regional lymph nodes is 1.2 mm. The coding is C 34.3; M 8255/3.

Source: NCI Genomic Data Commons file 4c7c65ee-3ef9-4167-9e55-c0dd2e6fad06 (TCGA-05-4396.96F3B48A-C5C4-40C3-A3D1-64477499C6E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).